Surgical pathology report (de-identified scan), TCGA case TCGA-AC-A8OP, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-AC-A8OP-01A (Primary Tumor).

[page 1 of 3]
Referring Physician:

DOB: Age: Gender: F

Ref#: Hosp#: Patient Location:

Date of Service: Date Received:

Case #:

Date Reported:

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

A. - E. RIGHT BREAST WITH AXILLARY SENTINEL LYMPH NODES, MASTECTOMY WITH SENTINEL LYMPH NODE BIOPSIES:

- Invasive ductal carcinoma, Nottingham grade 2.
- Invasive tumor nodule measures 18 mm in diameter.
- Ductal carcinoma in situ (DCIS), solid and cribriform architectural patterns, with associated comedo necrosis and calcifications.
- Resection margins free of tumor.
- Tumor is present 15 mm from the nearest margin (medial-anterior-inferior).
- Sites of previous biopsy identified.
- Six axillary sentinel lymph nodes, not tumor present (0/6).

PATHOLOGIC TUMOR STAGING SYNOPSIS:

Type and grade (invasive): Invasive ductal carcinoma, Nottingham grade 2.

Type and grade (in situ): DCIS, nuclear grade 2.

Primary tumor: pT1c.

Regional lymph nodes: pN0(i-)(sn).

Distant metastasis: pMX.

Pathologic stage: IA.

Lymphovascular invasion: Not identified.

Margin status: Negative (R0).

ICD O-3

Carcinoma, infiltrating duct

Date R Breast

C50.9

4/7/14

Case #:

Printed:

Page 1

This report continues... (FINAL)

[page 2 of 3]
Patient:

Case #

FINAL SURGICAL PATHOLOGY REPORT

Breast Invasive Tumor Staging Information

(AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol, Oct 2009)

This staging also incorporates:

Previous biopsy:

Breast profile:

Specimen type:

Specimen procedure:

Lymph node sampling:

Specimen integrity:

Specimen laterality:

Specimen size:

Total breast with axillary sentinel lymph nodes.
Mastectomy with sentinel lymph node biopsies.
Axillary lymph nodes (6 nodes in 4 specimens).
Single intact specimen.
Right.
21 x 15.5 x 4 cm.

INVASIVE TUMOR FEATURES:

Invasive tumor size:

Invasive tumor site:

Invasive tumor focality:

Histologic type:

Total Nottingham Grade:

Tubule formation:

Nuclear Pleomorphism:

Mitotic count for Nottingham:

Mitotic count:

18 mm.
Lower inner quadrant (3:30 aspect).
Single focus of invasive carcinoma.
Invasive ductal carcinoma.
2 of 3.
3 of 3.
2 of 3.
1 of 3.
Three mitoses in ten high power fields.

Lymphatic invasion:

Not identified.

MARGIN STATUS FOR INVASIVE COMPONENT:

Distance of tumor from margins:

Closest margin:

Other margins:

Negative (R0).

15 mm.

Anterior-medial-inferior (anterior margin overlying LIQ tumor)

Invasive carcinoma is at least 40 mm from all other margins.

IN-SITU CARCINOMA (DCIS) FEATURES:

DCIS extent:

DCIS present in association with invasive carcinoma, and extends into surrounding tissue (DCIS is associated with calcifications, and therefore may correspond to area of mammographically detected calcifications).

Pattern:

Nuclear grade:

Solid and cribriform.

Intermediate grade.

[page 3 of 3]
FINAL SURGICAL PATHOLOGY REPORT

Necrosis:
Calcifications:

Present.
Present.

Margin status for DCIS component:
Distance of In-situ from nearest margin:

Negative.
DCIS is at least 15 mm from the closest
anterior-inferior-medial margin.

LOBULAR CARCINOMA IN-SITU (LCIS):

Absent.

Skin:
Nipple:
Skeletal Muscle:

Unremarkable.
Unremarkable.
Not present.

INVASIVE PATHOLOGIC TUMOR STAGING (pTNM)

Primary tumor (pT):
Regional lymph nodes (pN):
Distant metastasis (pM):
Pathologic Stage:

pT1c.
pN0(i-)(sn).
pMX.
IA

RECEPTOR STATUS AND HER2/NEU:

Estrogen receptors:
Progesterone receptors:
Her2/neu:
KI-67 proliferative index:

POSITIVE (98% positive cells, strong).
POSITIVE (15% positive cells, strong).
Not overexpressed (IHC score 1+).
20% positive cells.

Signed by

Source of Specimen:

- A. Right axillary sentinel lymph node
- B. Right axillary sentinel lymph node
- C. Right axillary sentinel node
- D. Right axillary sentinel lymph node
- E. Right Breast

Clinical History/Operative Dx:

Right breast cancer

Intraoperative Diagnosis:

A. Right axillary sentinel lymph node . No tumor cells present. (Dr. . The intraoperative interpretation(s) was/were performed and rendered at

Case #:

Printed:

Source: NCI Genomic Data Commons file b8ca7d05-5e3f-4960-8ad9-3217b892eb86 (TCGA-AC-A8OP.F4F5C477-30BB-41EE-B188-B20DE019F30A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).